MMRF case MMRF_1143 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/bb1cf2aa-db7a-4b2b-a646-daeaf89c302d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 71.3 years (26,046 days); ISS stage: II; Days to last known disease status: 1,731 days (4.7 years); Days to last follow up: 1,731 days (4.7 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 187 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 997 days (2.7 years); Days to treatment end: 1,090 days (3.0 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,100 days (3.0 years); Days to treatment end: 1,100 days (3.0 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,202 days (3.3 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13: M Protein 3.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 49.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.85 mg/dL; Immunoglobulin G 51.6 g/L; Immunoglobulin A 0.348 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 3.4 µg/mL; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 9 ×10⁹/L; Absolute Neutrophil 7 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 34 g/L; Total Protein 10.4 g/dL; Glucose 10.7 mmol/L.
- Day 89 (ECOG 0): M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.53 mg/dL; Immunoglobulin G 14.4 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 7.5 g/dL; Glucose 9.63 mmol/L.
- Day 159 (ECOG 2): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.87 mg/dL; Immunoglobulin G 9.63 g/L; Immunoglobulin A 0.272 g/L; Immunoglobulin M 0.293 g/L; Beta 2 Microglobulin 2.2 µg/mL; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.18 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 9.63 mmol/L.
- Day 257: M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.69 mg/dL; Immunoglobulin G 12.1 g/L; Immunoglobulin A 0.337 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 2.6 µg/mL; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 7.59 mmol/L.
- Day 366: M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.48 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.68 mg/dL; Immunoglobulin G 14.4 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 14.5 mmol/L.
- Day 425: M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.7 mg/dL; Immunoglobulin G 14.6 g/L; Immunoglobulin A 0.308 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 7.4 g/dL; Glucose 5.72 mmol/L.
- Day 572 (ECOG 1): M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.74 mg/dL; Immunoglobulin G 15.7 g/L; Immunoglobulin A 0.329 g/L; Immunoglobulin M 0.198 g/L; Lactate Dehydrogenase 3.37 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 7.5 g/dL; Glucose 5.23 mmol/L.
- Day 656 (ECOG 0): M Protein 1.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.84 mg/dL; Immunoglobulin G 16.8 g/L; Immunoglobulin A 0.409 g/L; Immunoglobulin M 0.193 g/L; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 7.8 g/dL; Glucose 6.16 mmol/L.
- Day 786: M Protein 1.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 15.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 22.7 g/L; Immunoglobulin A 0.411 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 303 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 8.1 g/dL; Glucose 5.45 mmol/L.
- Day 856 (ECOG 1): M Protein 2.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 18.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.9 mg/dL; Immunoglobulin G 23.4 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.25 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 8.6 g/dL; Glucose 5.12 mmol/L.
- Day 964 (ECOG 0): M Protein 2.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 31.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.9 mg/dL; Immunoglobulin G 36.7 g/L; Immunoglobulin A 0.332 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 9 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 138 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 9.3 g/dL; Glucose 5.01 mmol/L.
- Day 1,081 (ECOG 0): M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.6 mg/dL; Immunoglobulin G 17.9 g/L; Immunoglobulin A 0.289 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 55.4 ×10⁹/L; Absolute Neutrophil 45.8 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 129 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 8.4 g/dL; Glucose 5.89 mmol/L.
- Day 1,142 (ECOG 1): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.7 mg/dL; Immunoglobulin G 12.8 g/L; Immunoglobulin A 0.462 g/L; Immunoglobulin M 0.211 g/L; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 8.9 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 7.4 g/dL; Glucose 5.67 mmol/L.
- Day 1,202 (ECOG 1): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.9 mg/dL; Immunoglobulin G 19 g/L; Immunoglobulin A 0.499 g/L; Immunoglobulin M 0.504 g/L; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 8.6 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 230 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 8.2 g/dL; Glucose 4.84 mmol/L.
- Day 1,346: M Protein 0.83 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.5 mg/dL; Hemoglobin 6.94 mmol/L; Leukocytes 7.38 ×10⁹/L; Absolute Neutrophil 4.31 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 7 g/dL; Glucose 6.82 mmol/L.
- Day 1,419: M Protein 0.63 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.2 mg/dL; Hemoglobin 7.63 mmol/L; Leukocytes 3.51 ×10⁹/L; Absolute Neutrophil 0.79 ×10⁹/L; Platelets 95 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.05 mmol/L; Albumin 37 g/L; Total Protein 7 g/dL; Glucose 5.61 mmol/L.
- Day 1,482: M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4 mg/dL; Lactate Dehydrogenase 6.15 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 3.54 ×10⁹/L; Absolute Neutrophil 1.55 ×10⁹/L; Platelets 106 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.1 mmol/L; Albumin 35 g/L; Total Protein 6.8 g/dL; Glucose 7.65 mmol/L.
- Day 1,573: M Protein 0.59 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.32 mg/dL; Lactate Dehydrogenase 6.95 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 4.05 ×10⁹/L; Absolute Neutrophil 1.82 ×10⁹/L; Platelets 109 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.18 mmol/L; Albumin 40 g/L; Total Protein 7.4 g/dL; Glucose 3.58 mmol/L.
- Day 1,669: M Protein 0.62 g/dL; Hemoglobin 6.01 mmol/L; Leukocytes 4.24 ×10⁹/L; Absolute Neutrophil 2.58 ×10⁹/L; Platelets 91 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 7.4 g/dL; Glucose 11.7 mmol/L.
- Day 1,731: M Protein 0.65 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.57 mg/dL; Hemoglobin 6.26 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.12 ×10⁹/L; Platelets 245 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 7.5 g/dL; Glucose 5.23 mmol/L.

Other clinical attributes
- Day -13: Weight: 76 kg; Height: 168 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1143_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 786 days (2.2 years).
- Sample MMRF_1143_2_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 786 days (2.2 years).
